Somatic mutation profile of tumor specimen TCGA-D7-6519-01A (aliquot TCGA-D7-6519-01A-11D-1800-08) from TCGA case TCGA-D7-6519, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Cardia, NOS; Tumor grade: G3; Age at diagnosis: 64.1 years (23,413 days).
Specimen TCGA-D7-6519-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d02db2b-a309-4a65-8256-6056682720a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-6519-10A (Blood Derived Normal), aliquot TCGA-D7-6519-10A-01D-1800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42420aec-601e-464c-9450-dca9aa4ebde8

The open-access MAF lists 54 somatic variants for this specimen: 40 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 12, Frame Shift Del 4, Nonsense Mutation 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD30A | c.1241C>A p.P414H (on ENST00000611781; = p.P358H on NM_052997.2) | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.667); catalogued as rs1245920742, COSV64607707, COSV64612682; called by muse, mutect2, varscan2
- ARHGEF11 | c.3805G>A p.G1269R | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV59353241; called by muse, mutect2, varscan2
- CASP8AP2 | c.3094C>T p.P1032S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52746097; called by muse, mutect2, varscan2
- CCHCR1 | c.180G>A p.M60I | Missense Mutation (SNP) | VAF 85/127 reads (67%) | SIFT tolerated (0.23); PolyPhen benign (0.096); catalogued as COSV66161224; called by muse, mutect2, varscan2
- CCNB3 | c.3493G>T p.V1165L | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52071750, COSV99330186; called by muse, mutect2, varscan2
- CNBD1 | c.178T>G p.L60V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs781715512, COSV72916701; called by muse, mutect2
- CNTN5 | c.928G>T p.V310F | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as COSV54296963; called by muse, mutect2, varscan2
- COG5 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs368331483, COSV51746899; called by muse, mutect2, varscan2
- DACH1 | c.692C>A p.T231N | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV57494698; called by muse, mutect2, varscan2
- GLI3 | c.3626C>A p.P1209H | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.276); catalogued as COSV67886965; called by muse, mutect2, varscan2
- H3C6 | c.53G>T p.R18L | Missense Mutation (SNP) | VAF 53/76 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.422); catalogued as COSV64519492; called by muse, mutect2, varscan2
- HIF1A | c.2068G>A p.V690M | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs761548161, COSV60188698; called by muse, mutect2, varscan2
- HMCN1 | c.9438T>A p.N3146K | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54889022; called by muse, mutect2
- HRNR | c.1516C>T p.R506* | Nonsense Mutation (SNP) | VAF 198/484 reads (41%) | catalogued as rs115929005; called by muse, mutect2, varscan2
- HS3ST3B1 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.316); catalogued as rs771325900, COSV62906309; called by muse, mutect2, varscan2
- KIF4B | c.1555C>A p.Q519K | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV70528572; called by muse, mutect2, varscan2
- MUC6 | c.6068_6069del p.T2023Sfs*76 | Frame Shift Del (DEL) | VAF 47/449 reads (10%) | catalogued as rs763124713; called by pindel, varscan2
- MYO1C | c.836A>G p.N279S (on ENST00000648651 / NM_001080779.2; = p.N244S on NM_033375.5) | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.091); catalogued as COSV62998875; called by muse, mutect2, varscan2
- NKX2-5 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV61298674; called by muse, mutect2, varscan2
- NME8 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.382); catalogued as rs777532091, COSV52247226; called by muse, mutect2, varscan2
- NRXN2 | c.4798G>A p.V1600M | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.683); catalogued as rs747979080, COSV55450459; called by muse, mutect2, varscan2
- NTRK3 | c.1561C>A p.H521N | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV58108289; called by muse, mutect2, varscan2
- OR5W2 | c.799T>A p.S267T | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as COSV60615307; called by muse, mutect2
- OR9G1 | c.81C>A p.F27L | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as COSV100380451, COSV56447576; called by muse, mutect2, varscan2
- PIK3C2B | c.1508C>G p.A503G | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.149); catalogued as COSV65803507; called by muse, mutect2
- PIWIL1 | c.1413C>A p.Y471* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as COSV55345412; called by muse, mutect2, varscan2
- PLD2 | c.1952G>T p.R651L | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.635); catalogued as COSV54004802; called by muse, mutect2, varscan2
- PPFIA3 | c.1421A>G p.D474G | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV61950674; called by muse, mutect2
- RPS6KA6 | c.2203C>T p.R735W | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1194188000, COSV53118036; called by muse, mutect2, varscan2
- SPHK1 | c.79A>G p.K27E (on ENST00000392496 / NM_001355139.2; = p.K41E on NM_021972.4) | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV60061674; called by muse, mutect2, varscan2
- TGFB1 | c.752A>C p.H251P | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.354); catalogued as COSV55724281; called by muse, mutect2, varscan2
- TMEM8B | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 42/54 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199969691, COSV65076011; called by muse, mutect2, varscan2
- TTC21B | c.370C>T p.H124Y | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.167); catalogued as COSV54629119; called by muse, mutect2, varscan2
- TYW5 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as COSV60666171; called by muse, mutect2, varscan2
- ZCCHC13 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766481122, COSV59866122; called by muse, mutect2, varscan2
- ZNF821 | c.659G>A p.G220E (on ENST00000425432 / NM_001376297.1; = p.G178E on NM_017530.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.014); catalogued as rs1444155251, COSV57987106; called by muse, mutect2
- ZP1 | c.1394C>A p.P465H | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV53923845; called by muse, mutect2, varscan2
- CSF1R | c.2210del p.F737Sfs*26 | Frame Shift Del (DEL) | VAF 38/125 reads (30%) | called by mutect2, pindel, varscan2
- FPR3 | c.719_735del p.L240Cfs*13 | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | called by mutect2, pindel, varscan2
- USP54 | c.1535_1538del p.V512Afs*3 | Frame Shift Del (DEL) | VAF 33/71 reads (46%) | called by mutect2, pindel, varscan2
- ADRM1 | c.1065C>T p.L355= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as rs1188537972, COSV53356647; called by muse, mutect2, varscan2
- ARHGAP30 | c.2619C>T p.D873= | Silent (SNP) | VAF 44/129 reads (34%) | catalogued as rs767853682, COSV63515716; called by muse, mutect2, varscan2
- CHUK | c.507C>G p.A169= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as COSV64917555; called by muse, mutect2, varscan2
- DUOX1 | c.3414C>T p.I1138= | Silent (SNP) | VAF 24/33 reads (73%) | catalogued as rs1159370213, COSV58479060; called by muse, mutect2, varscan2
- ERC2 | c.190C>T p.L64= | Silent (SNP) | VAF 69/157 reads (44%) | catalogued as COSV55611895; called by muse, mutect2, varscan2
- ITIH6 | c.450A>G p.E150= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV54487900; called by muse, mutect2, varscan2
- MDH1B | c.696G>A p.R232= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as COSV65589050; called by muse, mutect2, varscan2
- PREX2 | c.2205C>T p.V735= | Silent (SNP) | VAF 40/96 reads (42%) | catalogued as COSV55760887, COSV99908618; called by muse, mutect2, varscan2
- RTN1 | c.1101G>A p.S367= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs912145580, COSV50720712; called by muse, mutect2
- UPF1 | c.1563C>T p.A521= (on ENST00000599848 / NM_001297549.2; = p.A510= on NM_002911.4) | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as COSV53194939; called by muse, mutect2, varscan2
- VCX | c.582G>T p.P194= | Silent (SNP) | VAF 46/340 reads (14%) | catalogued as COSV58232163, COSV58233998; called by muse, varscan2
- VCX3A | c.522G>T p.L174= | Silent (SNP) | VAF 118/779 reads (15%) | catalogued as rs756843623, COSV66910458; called by muse, varscan2
- MRPL3 | c.630-7843G>C | Intron (SNP) | VAF 11/18 reads (61%) | catalogued as COSV99394723, COSV99394861; called by muse, mutect2, varscan2
- RPS3A | c.355-781G>A | Intron (SNP) | VAF 35/56 reads (63%) | catalogued as COSV56839949; called by muse, mutect2, varscan2
